Gene-level copy-number profile of tumor specimen TCGA-EU-5905-01A from TCGA case TCGA-EU-5905, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.0 years (24,475 days).
Specimen TCGA-EU-5905-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.a1a0ffaf-babf-4eb8-a747-f11d81f5f5ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EU-5905-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/51dfcf12-61ec-42a5-8cef-01e76f84ef8a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 29,521; copy number 4: 22,355; copy number 5: 5,499; copy number 6: 77; copy number 8: 42; copy number 9: 2,325.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EU-5905-01A-11D-1668-01): tumor purity 0.59, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,943 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:129,334,586–130,823,914, 40 genes, copy number 5: AC137695.1, AC137695.2, AL449212.1, RPL32P3, SNORA7B, EFCAB12, MBD4, IFT122, RHO, H1-8, PLXND1, RN7SL752P, AC023162.1, TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1, AC083906.3, TRH, AC083906.1, AC083906.5, AC083906.2, OR7E129P, OR7E21P, AC083906.4, ALG1L2, LINC02014, FAM86HP, LINC02021, ENPP7P3, AC130888.1, SNRPCP8, COL6A4P2, AC093004.1, COL6A5, COL6A6, PIK3R4, RN7SKP212, AC097105.1.
- chr3:131,533,555–132,285,410, 1 gene, copy number 5 (within-gene range 2–5): CPNE4.
- chr3:131,985,855–134,057,648, 37 genes, copy number 5: MIR5704, PSMC2P1, RPL7P16, ACP3, AC020633.1, NIP7P2, DNAJC13, ACAD11, NPHP3-ACAD11, ACKR4, HSPA8P19, UBA5, NPHP3, NPHP3-AS1, AC079942.1, TMEM108, TMEM108-AS1, BFSP2, AC055753.1, BFSP2-AS1, AC022296.2, AC022296.4, AC022296.3, AC022296.1, CDV3, TOPBP1, INHCAP, RNU6-678P, RNA5SP140, TF, AC080128.1, SRPRB, AC080128.2, RAB6B, C3orf36, SLCO2A1, LINC02000.
- chr3:134,477,706–138,633,376, 54 genes, copy number 5: ANAPC13, CEP63, AC026117.1, EPHB1, KY, AC016931.1, RNU6-1174P, RNA5SP141, AC092969.1, AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM.
- chr3:138,825,063–198,222,513, 1,039 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,985 genes, copy number 5–9 (broad region; genes not listed).
- chr10:44,712–133,761,125, 2,329 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
